TCGA case TCGA-AX-A2IN — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fe79ebe1-cd0a-4ce2-a86d-637c28354ed9

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Dead; Days to death: 947 days (2.6 years).

Diagnoses (3)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 63.7 years (23,275 days); Year of diagnosis: 2007; Method of diagnosis: Biopsy; FIGO stage: Stage IC; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 947 days (2.6 years).
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 85.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 21.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 4.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 288 days; Days to treatment end: 605 days (1.7 years); Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Subsequent primary of the breast (histology not recorded by GDC). Age at diagnosis: 64.4 years (23,532 days); Days to diagnosis: 257 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 271 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis.
3. Metastasis of diagnosis 1 (Endometrioid adenocarcinoma, NOS), site: Brain, NOS. Age at diagnosis: 64.7 years (23,633 days); Days to diagnosis: 358 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day 358 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 358 days.
- Days to follow up: 947 days (2.6 years); Disease response: With Tumor.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal.
- Timepoint category: Initial Diagnosis; Weight: 100 kg; Height: 157 cm; BMI: 40.6.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AX-A2IN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 60 mg.
  Slide TCGA-AX-A2IN-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 20; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AX-A2IN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AX-A2IN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 947 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 947 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 257 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AX-A2IN-01A-12D-A17U-01): tumor purity 0.8, ploidy 2.04, whole-genome doublings 0.
